Gene-level copy-number profile of tumor specimen TCGA-HL-7533-01A from TCGA case TCGA-HL-7533, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Tumor grade: G3; Age at diagnosis: 65.6 years (23,950 days).
Specimen TCGA-HL-7533-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d26df559-dd37-4fbc-9f51-6135ce3eca83.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HL-7533-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/faf17158-b170-4e36-b1e2-2a9bb8fddc0f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,328; copy number 2: 47,852; copy number 3: 4,663; copy number 4: 1,942; copy number 9: 2; copy number 14: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-HL-7533-01): tumor purity 0.63, ploidy 2.11, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 33 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:5,584,490–5,588,994, 1 gene, copy number 14: AL162253.1.
- chr19:9,083,112–9,539,734, 32 genes, copy number 9–14: OR1M4P, OR1M1, OR7G2, OR7G1, OR7G15P, OR7G3, ZNF317, OR7D2, ELOCP29, OR7E16P, OR7E25P, OR7D4, OR7D1P, OR7E24, OR7E18P, OR7E19P, OR7H1P, ZNF699, AC011451.1, ZNF559, ZNF559-ZNF177, AC011451.2, ZNF177, AC011451.3, ZNF266, AC011451.4, ZNF560, AC008567.2, AC008567.3, AC008567.1, ZNF426, ZNF426-DT.

Autosomal genes at a single copy (total copy number 1): 2,942. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
